Somatic mutation profile of tumor specimen TARGET-10-PASYAJ-09A (aliquot TARGET-10-PASYAJ-09A-01D) from TARGET case TARGET-10-PASYAJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,113 days).
Specimen TARGET-10-PASYAJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df6016e3-06ba-44a2-9a90-eebd0ad9da93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASYAJ-14A (Bone Marrow Normal), aliquot TARGET-10-PASYAJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3cdc68e-4b6c-4c54-8f4b-d3dd8685984d

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 2, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1700_1711del p.K567_L570del (on ENST00000521381 / NM_181523.3; = p.K297_L300del on NM_181504.4) | In Frame Del (DEL) | VAF 5/58 reads (9%) | hotspot (GDC flag); called by mutect2, pindel
- DAB2IP | c.2531G>A p.R844H (on ENST00000408936; = p.R816H on NM_032552.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs1347266207, COSV52260225; called by mutect2, varscan2
- DACT1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60020972; called by muse, mutect2, varscan2
- LGSN | c.1134G>T p.K378N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV65727303; called by muse, mutect2, varscan2
- MEGF11 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs865868911, COSV56551356; called by mutect2, varscan2
- PLCB4 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs747356766, COSV53802949; called by muse, mutect2, varscan2
- ROBO1 | c.2383C>A p.L795I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.091); called by muse, mutect2
- USP7 | c.530_531insAGAGAATCAT p.D178Efs*6 | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | called by mutect2, pindel*, varscan2
- ADAMTSL3 | c.1092T>A p.A364= | Silent (SNP) | VAF 13/41 reads (32%) | called by muse, varscan2
- CAT | c.978T>C p.F326= | Silent (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- DVL3 | c.1986C>T p.Y662= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1364441976, COSV99490981; called by muse, mutect2, varscan2
- MUC5AC | c.14901C>T p.C4967= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs188152234, COSV100611295; called by muse, mutect2, varscan2
- EIF3D | c.1207-82A>G | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TNFRSF10C | c.60+326C>A | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
